Somatic mutation profile of tumor specimen TCGA-25-1314-01A (aliquot TCGA-25-1314-01A-01W-0492-08) from TCGA case TCGA-25-1314, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 42.3 years (15,462 days).
Specimen TCGA-25-1314-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ab33ca6-da84-4bb1-9c5b-4127028c0d4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1314-10A (Blood Derived Normal), aliquot TCGA-25-1314-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8ab8eec-5f6a-4266-838c-54d5cf0c2606

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Frame Shift Del 5, Nonsense Mutation 5, Splice Site 2, Intron 1, 3'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 363/615 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99559592; called by muse, mutect2, varscan2
- ACSM4 | c.921C>T p.D307= | Splice Region (SNP) | VAF 115/423 reads (27%) | catalogued as rs747122297, COSV68069807; called by muse, mutect2, varscan2
- ALPK1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 110/305 reads (36%) | catalogued as COSV99454904; called by muse, mutect2, varscan2
- API5 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as COSV101124568, COSV66634407; called by muse, mutect2, varscan2
- ATAD2 | c.1071T>A p.S357R | Missense Mutation (SNP) | VAF 64/812 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV99785107; called by muse, mutect2
- BCO2 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100730429; called by muse, mutect2, varscan2
- BTBD7 | c.2593C>A p.P865T | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as rs865837983, COSV100598082; called by muse, mutect2, varscan2
- CALB2 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 94/406 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100226374; called by muse, mutect2, varscan2
- CCDC88A | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as COSV99710981; called by muse, mutect2, varscan2
- CCDC88A | c.548A>C p.Q183P | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99710983; called by muse, mutect2, varscan2
- CDH15 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV57028149, COSV99228708; called by muse, mutect2, varscan2
- CDRT1 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as COSV99887778; called by muse, mutect2
- CEP170 | c.3296G>T p.R1099M | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100317606; called by muse, mutect2
- CHST5 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1029752466, COSV100292096; called by muse, mutect2, varscan2
- CNGA4 | c.880C>G p.H294D | Missense Mutation (SNP) | VAF 101/354 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV101171844; called by muse, mutect2, varscan2
- CXCL9 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 95/308 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.773); catalogued as rs769576198, COSV53578725; called by muse, mutect2, varscan2
- DGKK | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 159/227 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV65707722; called by muse, mutect2, varscan2
- DNAJC30 | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 9/227 reads (4%) | catalogued as COSV99736835; called by muse, mutect2
- DOCK2 | c.3986A>T p.Y1329F | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56971390; called by muse, mutect2, varscan2
- EFS | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 27/148 reads (18%) | catalogued as COSV99391725; called by muse, mutect2, varscan2
- ERO1B | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.074); catalogued as COSV99934614; called by muse, mutect2, varscan2
- FARP2 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 126/312 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99885196; called by muse, mutect2, varscan2
- GOLGA6A | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99297323; called by muse, mutect2, varscan2
- GSDME | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs375973038; called by muse, mutect2, varscan2
- LRRC30 | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV101274440; called by muse, mutect2, varscan2
- LRRC30 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as rs1158790949, COSV67301607; called by muse, mutect2, varscan2
- MAP3K13 | c.715G>C p.G239R | Missense Mutation (SNP) | VAF 223/927 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407662; called by muse, varscan2
- MCF2L | c.1636G>A p.V546M (on ENST00000375608; = p.V514M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65048836; called by muse, mutect2, varscan2
- MYH7B | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 105/393 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV99483166; called by muse, mutect2, varscan2
- NIT2 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 101/510 reads (20%) | catalogued as COSV101237121; called by muse, mutect2, varscan2
- NR5A2 | c.1555T>A p.Y519N (on ENST00000367362 / NM_205860.3; = p.Y473N on NM_003822.5) | Missense Mutation (SNP) | VAF 176/462 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as COSV99370707, COSV99371497; called by muse, mutect2
- NT5DC3 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV101231018; called by muse, mutect2
- OR4D6 | c.248T>A p.V83E | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.655); catalogued as COSV100271791; called by muse, mutect2, varscan2
- OR9K2 | c.175G>C p.V59L (on ENST00000305377; = p.V37L on NM_001005243.1) | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV59532612; called by muse, mutect2, varscan2
- PAPOLA | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99354512; called by muse, mutect2, varscan2
- PDCD11 | c.4954A>T p.R1652* | Nonsense Mutation (SNP) | VAF 102/453 reads (23%) | catalogued as COSV53297992, COSV99588769; called by muse, mutect2, varscan2
- PLPP3 | c.85A>G p.S29G | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100984772; called by muse, mutect2, varscan2
- POPDC3 | c.805T>G p.S269A | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99633944; called by muse, mutect2, varscan2
- PPP1R15A | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); catalogued as rs746821743, COSV99566191; called by muse, mutect2, varscan2
- PSD2 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV99217426; called by muse, mutect2, varscan2
- RIF1 | c.6334G>A p.E2112K | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99691013; called by muse, mutect2, varscan2
- SEMA5A | c.2021A>G p.Q674R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.533); catalogued as COSV101228622; called by muse, mutect2, varscan2
- SON | c.6185C>T p.A2062V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV99279396; called by muse, mutect2
- SQLE | c.1405C>T p.L469F | Missense Mutation (SNP) | VAF 22/331 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99772503; called by muse, mutect2
- SRRD | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53226075; called by muse, mutect2
- STON2 | c.2363G>C p.R788P (on ENST00000649389 / NM_001366849.2; = p.R731P on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99964313, COSV99965039; called by muse, mutect2
- TTC7A | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as rs1317244338, COSV99766820; called by muse, mutect2, varscan2
- VN1R4 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1263703199, COSV100237515; called by muse, mutect2
- ZNF236 | c.5258C>G p.T1753R | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); catalogued as COSV99470960; called by muse, mutect2, varscan2
- ZNF292 | c.8077A>G p.S2693G | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100370895; called by muse, mutect2, varscan2
- ZNF442 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 176/1333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664463; called by muse, mutect2, varscan2
- ZNF566 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV101091621, COSV67574475; called by muse, mutect2, varscan2
- ZNF597 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100072102; called by muse, mutect2, varscan2
- ARNT | c.273-3_292del p.X91_splice | Splice Site (DEL) | VAF 37/219 reads (17%) | called by mutect2, pindel
- CLEC4G | c.487_497del p.E163Hfs*42 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
- FOSL2 | c.638del p.G213Vfs*7 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- GDAP1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDE3B | c.1936_1942del p.Q646Nfs*14 | Frame Shift Del (DEL) | VAF 27/218 reads (12%) | called by mutect2, pindel, varscan2
- PSD3 | c.2231_2255del p.E744Vfs*68 (on ENST00000440756; = p.E743Vfs*68 on NM_015310.4) | Frame Shift Del (DEL) | VAF 48/177 reads (27%) | called by mutect2, pindel
- TSG101 | c.641-3_654del p.X214_splice | Splice Site (DEL) | VAF 90/615 reads (15%) | called by mutect2, pindel
- ZNF646 | c.913_931del p.L305Nfs*41 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel
- ABCB8 | c.1960C>T p.L654= (on ENST00000297504 / NM_001282291.2; = p.L637= on NM_007188.5) | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as COSV99874819; called by muse, mutect2, varscan2
- AMIGO3 | c.1020C>T p.G340= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as COSV100246691; called by muse, mutect2, varscan2
- ARHGAP36 | c.981T>G p.S327= | Silent (SNP) | VAF 336/477 reads (70%) | catalogued as COSV52270795, COSV99358044; called by muse, mutect2, varscan2
- B3GALT4 | c.963G>C p.R321= | Silent (SNP) | VAF 95/480 reads (20%) | catalogued as COSV101005681; called by muse, mutect2, varscan2
- DRGX | c.201C>A p.A67= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100938376; called by muse, mutect2, varscan2
- DROSHA | c.1890T>C p.H630= | Silent (SNP) | VAF 16/278 reads (6%) | catalogued as COSV100757771; called by muse, mutect2
- ITPR2 | c.6846C>G p.S2282= | Silent (SNP) | VAF 111/418 reads (27%) | catalogued as COSV101190105; called by muse, mutect2, varscan2
- KISS1R | c.912T>G p.L304= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV99311916; called by muse, mutect2, varscan2
- MAP2 | c.4407A>G p.E1469= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV99561270; called by muse, mutect2, varscan2
- NDNF | c.1125C>T p.T375= | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as rs1351313519, COSV101113226; called by muse, mutect2, varscan2
- PMS1 | c.54C>T p.I18= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as COSV100575747; called by muse, mutect2, varscan2
- PPP1R12B | c.2001G>A p.E667= | Silent (SNP) | VAF 230/622 reads (37%) | catalogued as COSV51787589, COSV99295164; called by muse, mutect2, varscan2
- SUPT16H | c.1206C>T p.F402= | Silent (SNP) | VAF 67/353 reads (19%) | catalogued as COSV99360108; called by muse, mutect2, varscan2
- TENM4 | c.6060G>A p.L2020= | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as COSV99577418; called by muse, mutect2
- TFR2 | c.1758C>A p.S586= | Silent (SNP) | VAF 154/341 reads (45%) | catalogued as COSV99774679; called by muse, mutect2, varscan2
- TRIO | c.6663T>C p.S2221= | Silent (SNP) | VAF 56/224 reads (25%) | catalogued as COSV100702679; called by muse, mutect2, varscan2
- AC093512.2 | c.*1605G>C | 3'UTR (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100582183; called by muse, mutect2, varscan2
- CDCA7 | c.147+486A>G | Intron (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100143703; called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593196 C>T | 3'Flank (SNP) | VAF 12/41 reads (29%) | catalogued as rs1477935419; called by muse, mutect2, varscan2
